Somatic mutation profile of tumor specimen TARGET-10-PAPCED-09A (aliquot TARGET-10-PAPCED-09A-01D) from TARGET case TARGET-10-PAPCED, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,591 days).
Specimen TARGET-10-PAPCED-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a272026-c755-4351-b577-f909711ca8f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPCED-10A (Blood Derived Normal), aliquot TARGET-10-PAPCED-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ecb12d3d-a48f-4b9c-b12a-bdf171e0967c

The open-access MAF lists 56 somatic variants for this specimen: 38 protein-altering or splice-affecting, 7 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 7, Intron 6, Nonsense Mutation 4, 3'UTR 2, Frame Shift Del 1, 3'Flank 1, Splice Region 1, RNA 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.7502G>C p.S2501T | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as rs781076230; called by muse, mutect2, varscan2
- BPIFB6 | c.1172C>A p.S391* | Nonsense Mutation (SNP) | VAF 36/98 reads (37%) | catalogued as COSV62754115, COSV62754524; called by muse, mutect2, varscan2
- DIXDC1 | c.1295G>A p.R432H (on ENST00000440460 / NM_001037954.4; = p.R221H on NM_033425.4) | Missense Mutation (SNP) | VAF 4/91 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1555174807; called by muse, mutect2
- FOXO1 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65425534; called by muse, mutect2, varscan2
- JADE3 | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs781920545; called by muse, mutect2, varscan2
- MAPT | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52244341; called by muse, mutect2, varscan2
- MOGAT1 | c.952G>T p.E318* | Nonsense Mutation (SNP) | VAF 9/104 reads (9%) | catalogued as COSV71479957; called by muse, mutect2
- NEURL4 | c.2401G>A p.D801N | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs1301149855; called by muse, mutect2, varscan2
- RAB30 | c.582C>G p.I194M | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.288); catalogued as COSV52627427; called by muse, mutect2, varscan2
- RALGPS1 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.056); catalogued as rs201112886, COSV52217859; called by muse, mutect2, varscan2
- TBXT | c.474C>T p.I158= | Splice Region (SNP) | VAF 7/50 reads (14%) | catalogued as COSV51617179; called by muse, mutect2, varscan2
- TRIM58 | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs780952897, COSV63570014; called by muse, mutect2, varscan2
- TXNL4B | c.97G>C p.D33H | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as rs751426685; called by muse, mutect2, varscan2
- USP53 | c.983G>C p.R328T | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.269); catalogued as rs1360185909; called by muse, mutect2, varscan2
- ZNF460 | c.568C>T p.L190F | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1284012085; called by muse, mutect2
- BCCIP | c.912C>G p.I304M | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- CENPF | c.832C>T p.H278Y | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CLCN4 | c.1559G>A p.G520E | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPS1 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); called by muse, mutect2
- CTTNBP2 | c.362T>G p.M121R | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DPYS | c.976G>T p.D326Y | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELP2 | c.1868C>T p.S623L | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HECTD1 | c.5086C>G p.Q1696E | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.023); called by muse, mutect2
- IGKV2-30 | c.357del p.W119Cfs*? | Frame Shift Del (DEL) | VAF 22/26 reads (85%) | called by pindel*, varscan2
- KRTAP5-1 | c.155_156insCAGA p.C53Rfs*176 | Frame Shift Ins (INS) | VAF 5/11 reads (45%) | called by muse*, mutect2
- LIMS2 | c.520A>C p.T174P (on ENST00000355119 / NM_001161403.3; = p.T198P on NM_017980.4) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MMP14 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2
- MMP8 | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NEURL4 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLD5 | c.662C>T p.S221F (on ENST00000442594; = p.S159F on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- PRUNE2 | c.6032C>G p.S2011* | Nonsense Mutation (SNP) | VAF 12/121 reads (10%) | called by muse, mutect2
- PTGDS | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2, varscan2
- STX12 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- TAB3 | c.1727G>A p.R576K | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.018); called by muse, varscan2
- TMCO1 | c.115T>C p.S39P | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNFRSF10A | c.1362C>G p.F454L | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- TTN | c.20187C>G p.F6729L (on ENST00000591111; = p.F5802L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/156 reads (19%) | PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- UBR4 | c.8036C>G p.S2679C | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.401); called by muse, mutect2
- ARL6IP1 | c.87G>A p.V29= | Silent (SNP) | VAF 36/123 reads (29%) | catalogued as COSV58614346; called by muse, mutect2, varscan2
- DNAJC13 | c.4743G>C p.L1581= | Silent (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- MAGEE2 | c.1365G>T p.L455= | Silent (SNP) | VAF 35/91 reads (38%) | catalogued as COSV64898155; called by muse, mutect2, varscan2
- PPP1R26 | c.2367C>T p.D789= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as rs777369326; called by muse, mutect2, varscan2
- STAC3 | c.363G>A p.K121= | Silent (SNP) | VAF 29/142 reads (20%) | called by muse, mutect2, varscan2
- TDRD5 | c.1117C>T p.L373= | Silent (SNP) | VAF 48/137 reads (35%) | catalogued as rs760878417; called by muse, mutect2, varscan2
- ZMYM2 | c.663G>A p.Q221= | Silent (SNP) | VAF 41/84 reads (49%) | called by muse, mutect2, varscan2
- AC005008.2 | n.11C>G | RNA (SNP) | VAF 14/100 reads (14%) | called by muse, mutect2, varscan2
- DNAH7 | c.1353+1680G>A | Intron (SNP) | VAF 17/43 reads (40%) | catalogued as rs937700428; called by muse, mutect2
- GPD1 | c.361-247G>A | Intron (SNP) | VAF 18/44 reads (41%) | catalogued as rs905095676; called by muse, mutect2, varscan2
- IGKV2D-30 | chr2:89937679 ins CCG | 3'Flank (INS) | VAF 4/45 reads (9%) | called by mutect2, pindel
- NEURL4 | c.1366+19G>A | Intron (SNP) | VAF 5/36 reads (14%) | catalogued as rs765438801; called by muse, mutect2, varscan2
- POLI | c.-3G>C | 5'UTR (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2, varscan2
- SPATA31D4 | c.*33G>A | 3'UTR (SNP) | VAF 35/107 reads (33%) | called by muse, mutect2, varscan2
- SULF1 | c.2585+1532G>A | Intron (SNP) | VAF 29/103 reads (28%) | catalogued as rs1315052801; called by muse, mutect2, varscan2
- TTC25 | c.625+35del | Intron (DEL) | VAF 5/19 reads (26%) | called by mutect2, pindel, varscan2
- VEGFC | c.*76G>A | 3'UTR (SNP) | VAF 13/29 reads (45%) | catalogued as COSV99710146; called by mutect2, varscan2
- ZIC4 | c.688+1918G>A | Intron (SNP) | VAF 14/60 reads (23%) | catalogued as rs1260503731; called by muse, mutect2
